Somatic mutation profile of tumor specimen TCGA-A3-3347-01A (aliquot TCGA-A3-3347-01A-02D-1386-10) from TCGA case TCGA-A3-3347, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 76.6 years (27,966 days).
Specimen TCGA-A3-3347-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93414525-6eb2-4e6c-abd2-0c2c0f1d69e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3347-11A (Solid Tissue Normal), aliquot TCGA-A3-3347-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fb439ee-8406-4d7e-818d-7d47066e3917

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 17, Silent 8, Frame Shift Del 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.6981G>A p.M2327I | Missense Mutation (SNP) | VAF 82/445 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs878855328, COSV63868602, COSV63869693, COSV63874461; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.3923T>C p.F1308S | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101315533; called by muse, mutect2
- C3orf70 | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.237); catalogued as COSV58591048; called by muse, mutect2, varscan2
- CARD10 | c.1934T>C p.M645T | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV52660699; called by muse, mutect2
- CSMD3 | c.6038C>T p.T2013I (on ENST00000297405 / NM_001363185.1; = p.T1909I on NM_052900.3) | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52202200, COSV52340305; called by muse, mutect2, varscan2
- DCHS1 | c.3652G>C p.A1218P | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.916); catalogued as COSV100201557; called by muse, varscan2
- DST | c.1264G>A p.V422M (on ENST00000361203 / NM_001374722.1; = p.V96M on NM_001723.6) | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.299); catalogued as COSV55044555; called by muse, mutect2, varscan2
- GRIK5 | c.2484G>T p.W828C | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53486941; called by muse, mutect2, varscan2
- KLF8 | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as COSV63849018; called by muse, mutect2, varscan2
- OR51B4 | c.739G>C p.V247L | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.718); catalogued as COSV66517966; called by muse, mutect2, varscan2
- PAFAH1B1 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.219); catalogued as COSV68210663; called by muse, mutect2, varscan2
- PCDHGA1 | c.2421G>C p.Q807H | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.547); catalogued as COSV65300266; called by muse, mutect2
- PER2 | c.542T>A p.V181D | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV54528588; called by muse, mutect2, varscan2
- PLEKHA6 | c.243G>T p.W81C | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55341126; called by muse, mutect2, varscan2
- QRFPR | c.1091A>G p.N364S | Missense Mutation (SNP) | VAF 77/428 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV57680562; called by muse, mutect2, varscan2
- TLL2 | c.2590A>C p.S864R | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV63576536; called by muse, mutect2
- TRPC1 | c.1354G>C p.E452Q (on ENST00000476941 / NM_001251845.2; = p.E418Q on NM_003304.4) | Missense Mutation (SNP) | VAF 34/808 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.091); catalogued as COSV99858285; called by muse, mutect2
- DERL2 | c.333del p.F111Lfs*5 | Frame Shift Del (DEL) | VAF 23/106 reads (22%) | called by mutect2, pindel, varscan2
- MIDEAS | c.1920_1923del p.A641Tfs*62 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | called by mutect2, pindel, varscan2
- PBRM1 | c.1637_1640del p.F546Wfs*22 | Frame Shift Del (DEL) | VAF 47/271 reads (17%) | called by mutect2, pindel, varscan2
- ZFP91 | c.1204_1209del p.C402_E403del | In Frame Del (DEL) | VAF 29/160 reads (18%) | called by mutect2, pindel, varscan2
- ABCC2 | c.285A>G p.T95= | Silent (SNP) | VAF 45/259 reads (17%) | catalogued as COSV64971430; called by muse, mutect2, varscan2
- CCDC88B | c.1405C>A p.R469= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV57268619; called by muse, varscan2
- DOCK10 | c.4653A>T p.S1551= | Silent (SNP) | VAF 10/167 reads (6%) | catalogued as COSV51371922, COSV99287863; called by muse, mutect2
- EIF2A | c.18G>C p.P6= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as COSV53526624; called by muse, mutect2, varscan2
- ITIH4 | c.795C>T p.P265= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as rs375739396, COSV56579536; called by muse, mutect2, varscan2
- MAGED1 | c.567G>A p.K189= | Silent (SNP) | VAF 32/159 reads (20%) | catalogued as COSV58517095; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1461G>A p.R487= | Silent (SNP) | VAF 39/194 reads (20%) | catalogued as rs756929387, COSV50080975; called by muse, mutect2, varscan2
- TRIM21 | c.405C>T p.Y135= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV54346521; called by muse, mutect2, varscan2
